Somatic mutation profile of tumor specimen HCM-CSHL-0161-C18-01A (aliquot HCM-CSHL-0161-C18-01A-11D-A78T-36) from HCMI case HCM-CSHL-0161-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: GB; Age at diagnosis: 74.5 years (27,209 days).
Specimen HCM-CSHL-0161-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62af0ed3-a0a0-4b42-b8b2-497287f05bfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0161-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0161-C18-11A-11D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2839eba2-d6a2-40e2-ab6c-6c9f1aa53ed7

The open-access MAF lists 208 somatic variants for this specimen: 149 protein-altering or splice-affecting, 47 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 47, Nonsense Mutation 11, Frame Shift Del 7, 5'UTR 4, Intron 4, 3'UTR 3, Frame Shift Ins 3, Splice Site 3, Splice Region 2, In Frame Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1973G>A p.R658Q (on ENST00000281708 / NM_001349798.2; = p.R578Q on NM_018315.5) | Missense Mutation (SNP) | VAF 93/382 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs759610249, COSV55905466; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 106/423 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 75/279 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.330_332del p.K111del | In Frame Del (DEL) | VAF 13/44 reads (30%) | hotspot (GDC flag); called by mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 22/75 reads (29%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 182/470 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY5 | c.3163C>T p.R1055C | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs377330980; called by muse, mutect2, varscan2
- AHNAK2 | c.7886G>A p.R2629Q | Missense Mutation (SNP) | VAF 161/602 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs572087329; called by muse, mutect2, varscan2
- ALK | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 87/322 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs769061878, COSV66555598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANTKMT | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 91/351 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748118024; called by muse, mutect2, varscan2
- APC | c.4391_4394del p.E1464Vfs*8 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | catalogued as rs387906234; called by mutect2, pindel, varscan2
- APC2 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 103/330 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.04); catalogued as rs949864607; called by muse, mutect2, varscan2
- BAG4 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs774897872; called by muse, mutect2, varscan2
- BNC1 | c.2387T>G p.L796R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs139607641, COSV61757499; called by muse, mutect2, varscan2
- BRDT | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.838); catalogued as rs1487473834; called by muse, mutect2, varscan2
- BTN3A1 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs773029993; called by muse, mutect2, varscan2
- BTN3A3 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 86/390 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1411664379; called by muse, mutect2, varscan2
- CD200R1L | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142953807, COSV68004161; called by muse, mutect2, varscan2
- CFAP58 | c.1674+2T>C p.X558_splice | Splice Site (SNP) | VAF 19/71 reads (27%) | catalogued as rs773414802; called by muse, mutect2, varscan2
- CNTN3 | c.1845A>C p.Q615H | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV55161936, COSV99726459; called by muse, mutect2, varscan2
- CPS1 | c.4357C>T p.R1453W | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933813349, CM104561, COSV51806734; called by muse, mutect2, varscan2
- CSPG4 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs148728726, COSV104413993; called by muse, mutect2, varscan2
- CUL9 | c.2245G>A p.V749M | Missense Mutation (SNP) | VAF 149/509 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs376469889; called by muse, mutect2, varscan2
- DBP | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 89/361 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55337120; called by muse, mutect2, varscan2
- DMD | c.5326-2A>T p.X1776_splice | Splice Site (SNP) | VAF 39/74 reads (53%) | catalogued as rs771473685; called by muse, mutect2, varscan2
- DOCK5 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs369802050; called by muse, mutect2, varscan2
- DSCAML1 | c.6181G>A p.A2061T (on ENST00000321322; = p.A2001T on NM_020693.4) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs778403842, COSV100356106; called by muse, mutect2, varscan2
- ELAPOR2 | c.917A>G p.N306S (on ENST00000450689 / NM_001142749.3; = p.N139S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs762692749; called by muse, mutect2, varscan2
- ELFN1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 96/334 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1448289526; called by muse, mutect2, varscan2
- EPPK1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.533); catalogued as rs934671022; called by muse, mutect2, varscan2
- EXOSC10 | c.1460C>T p.T487M | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs748350072, COSV58666686; called by muse, mutect2, varscan2
- FAM47A | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1224051046, COSV60497362; called by muse, mutect2, varscan2
- FAM47B | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 88/159 reads (55%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1003154042, COSV61453303, COSV61453412; called by muse, mutect2, varscan2
- FBXO34 | c.1607C>A p.S536Y | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV58256660; called by muse, mutect2, varscan2
- FBXO9 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs1290789368, COSV99762214; called by muse, mutect2, varscan2
- FGD6 | c.2221A>G p.T741A | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1386408999; called by muse, mutect2, varscan2
- FNDC1 | c.3848C>T p.T1283M | Missense Mutation (SNP) | VAF 94/380 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs780449351, COSV51939560; called by muse, mutect2, varscan2
- FRY | c.4136C>T p.S1379L | Missense Mutation (SNP) | VAF 163/583 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.322); catalogued as rs746244232, COSV100968782; called by muse, mutect2, varscan2
- GCGR | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 113/461 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs552010052, COSV68779776; called by muse, mutect2, varscan2
- GDF5 | c.149G>T p.R50M | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as COSV65502226; called by muse, mutect2, varscan2
- GLIPR2 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 81/340 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs949478315; called by muse, mutect2, varscan2
- GPR182 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs776962475, COSV55626621, COSV55627041; called by muse, mutect2, varscan2
- GRK1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 108/362 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371556611; called by muse, mutect2, varscan2
- H2BC10 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 86/384 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); catalogued as rs751586556, COSV59952772; called by muse, mutect2, varscan2
- HHAT | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs777581246, COSV54802868; called by muse, mutect2, varscan2
- IFT46 | c.763C>T p.R255W (on ENST00000264021 / NM_001168618.2; = p.R306W on NM_020153.3) | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs782137705; called by muse, mutect2, varscan2
- ING1 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 63/186 reads (34%) | catalogued as COSV58168738, COSV58170541; called by muse, mutect2, varscan2
- ITGA5 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.115); catalogued as rs369973451, COSV53217784; called by muse, mutect2
- LCE2A | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 111/406 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100909179; called by muse, mutect2, varscan2
- LILRB5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 136/535 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs923890744, COSV60259321; called by muse, mutect2, varscan2
- LPAR3 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs889787610, COSV65453028; called by muse, mutect2, varscan2
- LRAT | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 103/395 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs776906234; called by muse, mutect2, varscan2
- LRPPRC | c.1734G>A p.T578= | Splice Region (SNP) | VAF 86/355 reads (24%) | catalogued as rs201889668; called by muse, mutect2, varscan2
- MARCO | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.198); catalogued as rs200590124; called by muse, mutect2
- MINDY4 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); catalogued as rs764087591, COSV54675426; called by muse, mutect2, varscan2
- MPDZ | c.5113C>T p.R1705C | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs529673809, COSV100058108; called by muse, mutect2, varscan2
- MYBPC3 | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs730880563, COSV57033777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP5 | c.2011_2012del p.L671Vfs*6 | Frame Shift Del (DEL) | VAF 72/350 reads (21%) | catalogued as rs775483680; called by pindel, varscan2
- NR4A3 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100432745; called by muse, mutect2, varscan2
- ODF1 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 105/644 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs755889668; called by muse, mutect2, varscan2
- OR2T34 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 53/429 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs746667499, COSV60899605, COSV60900803; called by muse, mutect2, varscan2
- PCDHGB2 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 168/631 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs533999436; called by muse, mutect2, varscan2
- PCNX2 | c.4412G>A p.G1471D | Missense Mutation (SNP) | VAF 91/347 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV50874530; called by muse, mutect2, varscan2
- PDHA1 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100870313, COSV63328683; called by muse, mutect2, varscan2
- PIEZO2 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1409494922; called by muse, mutect2, varscan2
- PKD1 | c.5527G>A p.G1843S | Missense Mutation (SNP) | VAF 122/418 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as rs367732509; called by muse, mutect2, varscan2
- PLS3 | c.533T>C p.I178T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1027209292, COSV104388351; called by muse, mutect2, varscan2
- PRRC2B | c.3379C>T p.R1127* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as rs1300991170; called by muse, mutect2, varscan2
- RALB | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs141928830; called by muse, mutect2, varscan2
- RBFOX1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1236617150, COSV60955885, COSV60960221; called by muse, mutect2, varscan2
- SALL3 | c.1318C>A p.R440S | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73306627; called by muse, mutect2, varscan2
- SIPA1L1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1401169832; called by muse, mutect2, varscan2
- SLC22A13 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528880884; called by muse, mutect2, varscan2
- SLC27A1 | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 56/201 reads (28%) | catalogued as rs762073668; called by muse, mutect2, varscan2
- SLC6A1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV55114842; called by muse, mutect2, varscan2
- SLFNL1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs760307090; called by muse, mutect2, varscan2
- SMAD4 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs794726995, COSV61684489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOX1 | c.672_683del p.H225_P228del | In Frame Del (DEL) | VAF 51/126 reads (40%) | catalogued as rs915453765; called by mutect2, varscan2
- SOX9 | c.1145_1146dup p.T383* | Frame Shift Ins (INS) | VAF 73/147 reads (50%) | catalogued as COSV55426030; called by mutect2, pindel, varscan2
- SPIRE1 | c.1561C>T p.R521* (on ENST00000409402 / NM_001128626.2; = p.R507* on NM_020148.3) | Nonsense Mutation (SNP) | VAF 69/281 reads (25%) | catalogued as rs747265516, COSV59152682; called by muse, mutect2, varscan2
- SPON1 | c.2033C>G p.S678W | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59965501; called by muse, mutect2, varscan2
- TACR3 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 91/380 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs201938668, COSV100510776; called by muse, mutect2, varscan2
- TM7SF3 | c.933del p.F311Lfs*13 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as rs778819221; called by mutect2, pindel, varscan2
- TRANK1 | c.2596C>T p.R866* | Nonsense Mutation (SNP) | VAF 80/254 reads (31%) | catalogued as rs535417879, COSV100084941; called by muse, mutect2, varscan2
- TRPM8 | c.2624C>G p.A875G | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV61222211; called by mutect2, varscan2
- UHRF2 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.053); catalogued as rs371780891; called by muse, mutect2, varscan2
- ZIK1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100277632; called by muse, mutect2, varscan2
- ZNF624 | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 26/108 reads (24%) | catalogued as rs754763390; called by muse, mutect2, varscan2
- ABCA12 | c.6665T>A p.F2222Y (on ENST00000272895 / NM_173076.3; = p.F1904Y on NM_015657.3) | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADAMTS16 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 78/311 reads (25%) | called by muse, mutect2, varscan2
- ARMH4 | c.478A>C p.K160Q | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- BCL9L | c.4374_4377del p.L1459Wfs*97 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | called by mutect2, pindel, varscan2
- C2CD2L | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 127/442 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAND2 | c.662G>A p.R221Q (on ENST00000456430 / NM_001162499.2; = p.R128Q on NM_012298.3) | Missense Mutation (SNP) | VAF 98/365 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPERE | c.1867G>A p.V623M | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CYP21A2 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 420/759 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, varscan2
- DND1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 144/381 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EFCAB5 | c.2201C>G p.T734R | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ELMO2 | c.2153A>G p.H718R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EPHA3 | c.2735C>A p.T912N | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- EPHA5 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM20B | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); called by muse, mutect2
- FAM47B | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- FARP1 | c.2446G>T p.E816* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- FAT4 | c.5870T>A p.L1957Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- FMO5 | c.235T>G p.Y79D | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FZD7 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 129/462 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GOLGA8R | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- HDGFL3 | c.220A>C p.K74Q | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HNRNPD | c.104_105del p.Q35Rfs*34 | Frame Shift Del (DEL) | VAF 74/374 reads (20%) | called by mutect2, pindel, varscan2
- JAG1 | c.3350A>G p.E1117G | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KCNC3 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KDM4B | c.1868C>A p.P623Q | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLC1 | c.1489-4A>G | Splice Region (SNP) | VAF 56/160 reads (35%) | called by muse, mutect2
- LSM14A | c.1053_1054insTTGCC p.D352Lfs*42 | Frame Shift Ins (INS) | VAF 54/206 reads (26%) | called by mutect2, pindel, varscan2
- MAST1 | c.2548G>T p.A850S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPND | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MUTYH | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 105/685 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH9 | c.340T>C p.S114P | Missense Mutation (SNP) | VAF 139/540 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRK | c.2902G>T p.D968Y | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- OAS1 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 18/383 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- OR2T10 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 60/568 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- OR52E6 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- OR8B2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR9Q2 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PABPC4 | c.697T>A p.F233I | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH10 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PCDHB16 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PCGF6 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- PCNX3 | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 117/518 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- PIP5K1C | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 84/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRDM15 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRRC2B | c.6323C>A p.A2108D | Missense Mutation (SNP) | VAF 95/348 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RIMS1 | c.3875C>G p.T1292R | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SEPSECS | c.961G>C p.D321H | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETMAR | c.910_911del p.L304Vfs*14 | Frame Shift Del (DEL) | VAF 44/234 reads (19%) | called by pindel, varscan2
- SHANK1 | c.5708A>G p.D1903G | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SIN3A | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SLC39A10 | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC45A3 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 77/329 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ST3GAL1 | c.542T>G p.V181G | Missense Mutation (SNP) | VAF 89/186 reads (48%) | PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SYNE1 | c.8183_8184insG p.E2729Rfs*5 (on ENST00000367255 / NM_182961.4; = p.E2736Rfs*5 on NM_033071.3) | Frame Shift Ins (INS) | VAF 46/209 reads (22%) | called by mutect2, pindel*, varscan2
- SYNE1 | c.3438A>C p.Q1146H (on ENST00000367255 / NM_182961.4; = p.Q1153H on NM_033071.3) | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TAF5L | c.1628dup p.Y543* | Nonsense Mutation (INS) | VAF 73/327 reads (22%) | called by mutect2, pindel, varscan2
- TATDN2 | c.1324T>C p.S442P | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMTC4 | c.2065C>A p.H689N (on ENST00000376234 / NM_001350577.2; = p.H708N on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TNPO1 | c.480del p.Q161Rfs*11 | Frame Shift Del (DEL) | VAF 50/209 reads (24%) | called by mutect2, pindel, varscan2
- WDR76 | c.1033-1G>C p.X345_splice | Splice Site (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- XRCC1 | c.1829G>T p.R610L | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- AGO4 | c.2007C>T p.Y669= | Silent (SNP) | VAF 49/170 reads (29%) | catalogued as COSV100942936; called by muse, mutect2, varscan2
- AMER2 | c.372C>T p.R124= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs1340350359, COSV100766199; called by muse, mutect2, varscan2
- ARHGEF26 | c.954C>T p.R318= | Silent (SNP) | VAF 140/579 reads (24%) | called by muse, mutect2, varscan2
- ASPG | c.1248G>A p.A416= | Silent (SNP) | VAF 32/313 reads (10%) | catalogued as rs151283874; called by muse, mutect2, varscan2
- BNC1 | c.2712T>C p.D904= | Silent (SNP) | VAF 58/224 reads (26%) | catalogued as rs143642352, COSV100597560; called by muse, mutect2, varscan2
- BSN | c.3000C>A p.S1000= | Silent (SNP) | VAF 84/306 reads (27%) | catalogued as COSV56514059; called by muse, mutect2, varscan2
- CACNA2D3 | c.1662T>C p.Y554= | Silent (SNP) | VAF 27/163 reads (17%) | called by muse, mutect2, varscan2
- CAND2 | c.3645C>T p.A1215= (on ENST00000456430 / NM_001162499.2; = p.A1098= on NM_012298.3) | Silent (SNP) | VAF 102/402 reads (25%) | called by muse, mutect2, varscan2
- CCL4 | c.12C>T p.C4= | Silent (SNP) | VAF 26/571 reads (5%) | catalogued as rs199619169; called by muse, mutect2
- CDH8 | c.540C>T p.S180= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100182316; called by muse, varscan2
- CLEC18B | c.858C>T p.Y286= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as rs774779300; called by muse, mutect2, varscan2
- CNTNAP4 | c.2445G>A p.A815= | Silent (SNP) | VAF 44/197 reads (22%) | catalogued as rs1291873267, COSV56697688; called by muse, mutect2, varscan2
- EHD2 | c.645C>T p.R215= | Silent (SNP) | VAF 38/173 reads (22%) | catalogued as rs1043214730, COSV54411427; called by muse, mutect2, varscan2
- EZHIP | c.615C>T p.H205= | Silent (SNP) | VAF 68/131 reads (52%) | catalogued as rs781928344; called by muse, mutect2, varscan2
- FERD3L | c.417G>T p.R139= | Silent (SNP) | VAF 66/296 reads (22%) | called by muse, mutect2, varscan2
- FN1 | c.3063G>A p.R1021= | Silent (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- GABBR2 | c.702C>T p.N234= | Silent (SNP) | VAF 63/321 reads (20%) | catalogued as rs759372813, COSV52316761; called by muse, mutect2, varscan2
- GRID1 | c.2244C>T p.Y748= | Silent (SNP) | VAF 63/282 reads (22%) | catalogued as rs543588600; called by muse, mutect2, varscan2
- GUCY1A2 | c.939T>C p.P313= | Silent (SNP) | VAF 56/215 reads (26%) | catalogued as COSV99977053; called by muse, mutect2, varscan2
- HEY2 | c.804C>T p.A268= | Silent (SNP) | VAF 50/148 reads (34%) | catalogued as COSV100856275, COSV64240839; called by muse, mutect2, varscan2
- HLTF | c.982C>T p.L328= | Silent (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- HOXA13 | c.948C>A p.A316= | Silent (SNP) | VAF 83/298 reads (28%) | called by muse, mutect2, varscan2
- ITGA3 | c.1953G>A p.L651= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs1041102504; called by muse, mutect2
- ITGA4 | c.105C>T p.N35= | Silent (SNP) | VAF 87/338 reads (26%) | catalogued as rs1186977900, COSV52003081; called by muse, mutect2, varscan2
- KLHL21 | c.1488G>A p.P496= | Silent (SNP) | VAF 58/278 reads (21%) | catalogued as rs370458102; called by muse, mutect2, varscan2
- LAMA1 | c.3288G>T p.G1096= | Silent (SNP) | VAF 18/565 reads (3%) | catalogued as COSV67531559; called by muse, mutect2
- LIMD1 | c.1050G>C p.P350= | Silent (SNP) | VAF 96/492 reads (20%) | called by muse, mutect2, varscan2
- MLNR | c.1017C>T p.V339= | Silent (SNP) | VAF 101/375 reads (27%) | called by muse, mutect2, varscan2
- OR2A14 | c.771G>A p.T257= | Silent (SNP) | VAF 156/383 reads (41%) | catalogued as COSV68718293, COSV68718667; called by muse, mutect2, varscan2
- PCDH10 | c.1326G>A p.A442= | Silent (SNP) | VAF 56/201 reads (28%) | catalogued as COSV52101927; called by muse, mutect2, varscan2
- PRRT2 | c.987C>T p.I329= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs368411419, COSV54884812; called by muse, mutect2
- PTP4A3 | c.312C>T p.C104= | Silent (SNP) | VAF 110/262 reads (42%) | catalogued as rs150025897; called by muse, mutect2, varscan2
- RAB8A | c.561G>A p.Q187= | Silent (SNP) | VAF 92/312 reads (29%) | catalogued as COSV99507113; called by muse, mutect2, varscan2
- RASGRF2 | c.2376C>T p.L792= | Silent (SNP) | VAF 13/330 reads (4%) | called by muse, mutect2
- ROPN1B | c.45G>A p.P15= | Silent (SNP) | VAF 53/180 reads (29%) | catalogued as COSV52542902, COSV52543324; called by muse, mutect2, varscan2
- RYR1 | c.879C>T p.T293= | Silent (SNP) | VAF 134/498 reads (27%) | catalogued as rs371599963; ClinVar: likely benign; called by muse, mutect2, varscan2
- SIN3B | c.2484C>T p.S828= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as rs777140194; called by muse, mutect2, varscan2
- SRSF11 | c.393G>A p.V131= | Silent (SNP) | VAF 77/216 reads (36%) | called by muse, mutect2, varscan2
- STK25 | c.930G>A p.A310= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs370416984; called by muse, mutect2, varscan2
- TBC1D1 | c.2016G>A p.P672= | Silent (SNP) | VAF 71/266 reads (27%) | catalogued as rs1373145747; called by muse, mutect2, varscan2
- TRIM9 | c.291C>T p.N97= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1464157944; called by muse, mutect2, varscan2
- TTBK2 | c.2883A>G p.P961= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs757518859; called by muse, mutect2, varscan2
- UNC80 | c.2700C>T p.I900= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as rs995706379, COSV55899628; called by muse, mutect2, varscan2
- WDR25 | c.831C>T p.N277= | Silent (SNP) | VAF 91/388 reads (23%) | catalogued as rs758971019, COSV58939543; called by muse, mutect2, varscan2
- WDR64 | c.1110C>T p.A370= | Silent (SNP) | VAF 52/216 reads (24%) | catalogued as rs142859030; called by muse, mutect2, varscan2
- ZFHX4 | c.9000C>T p.G3000= | Silent (SNP) | VAF 64/182 reads (35%) | catalogued as rs1183735569, COSV50565031; called by muse, mutect2, varscan2
- ZNF208 | c.873C>A p.G291= | Silent (SNP) | VAF 66/298 reads (22%) | called by muse, mutect2, varscan2
- ATP6V0E1 | chr5:173020854 G>A | 3'Flank (SNP) | VAF 121/462 reads (26%) | called by muse, mutect2, varscan2
- CABIN1 | c.*25C>T | 3'UTR (SNP) | VAF 62/216 reads (29%) | catalogued as rs199716373, COSV99573202; called by muse, mutect2
- CCNQ | c.*97C>T | 3'UTR (SNP) | VAF 124/248 reads (50%) | called by muse, mutect2, varscan2
- CLASP1 | c.196-649C>T | Intron (SNP) | VAF 31/123 reads (25%) | catalogued as rs774196943; called by muse, mutect2, varscan2
- CYB561 | c.-13-512C>T | Intron (SNP) | VAF 34/136 reads (25%) | catalogued as rs1311622526, COSV62539520; called by muse, mutect2
- EAF1 | c.-4G>A | 5'UTR (SNP) | VAF 106/398 reads (27%) | called by muse, mutect2, varscan2
- HEXA | c.1421+38G>A | Intron (SNP) | VAF 54/196 reads (28%) | called by muse, mutect2, varscan2
- MPPED1 | c.-52G>A | 5'UTR (SNP) | VAF 42/172 reads (24%) | called by muse, mutect2
- POTEF | c.*4G>T | 3'UTR (SNP) | VAF 146/469 reads (31%) | called by muse, mutect2, varscan2
- SEC23A | c.279+69G>A | Intron (SNP) | VAF 8/102 reads (8%) | catalogued as rs1222223683; called by muse, mutect2
- SLC9A3 | c.-30G>A | 5'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- SYT14 | c.-6C>T | 5'UTR (SNP) | VAF 85/353 reads (24%) | called by muse, mutect2, varscan2
